Somatic mutation profile of tumor specimen TARGET-10-PARFDW-09A (aliquot TARGET-10-PARFDW-09A-01D) from TARGET case TARGET-10-PARFDW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,338 days).
Specimen TARGET-10-PARFDW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52b0d8d0-8f94-4e99-ac15-86dbb53412ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARFDW-14A (Bone Marrow Normal), aliquot TARGET-10-PARFDW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8972c6e-bae2-410e-8caa-7e17c772ef99

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Intron 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXL7 | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs776522515, COSV61642885; called by muse, mutect2
- CRACD | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- HECA | c.1386T>G p.C462W | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAST4 | c.5440C>G p.Q1814E (on ENST00000403625 / NM_001164664.2; = p.Q1625E on NM_015183.3) | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.287); called by muse, mutect2
- PKDREJ | c.980T>A p.V327D | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by mutect2, varscan2
- PTPRQ | c.3243A>T p.K1081N (on ENST00000616559; = p.K1039N on NM_001145026.2) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- RBM14 | c.798G>A p.M266I | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SLC23A2 | c.80C>A p.A27E | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.011); called by muse, mutect2
- TRGV4 | chr7:38353707 TCACTGTGCCCA>CC | Missense Mutation (DEL) | VAF 28/74 reads (38%) | called by pindel, varscan2*
- UBA2 | c.650-1G>A p.X217_splice | Splice Site (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- ZC3H12C | c.1415G>A p.C472Y | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- CHD8 | c.5649C>G p.A1883= (on ENST00000646647 / NM_001170629.2; = p.A1604= on NM_020920.4) | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs769223487; called by muse, mutect2, varscan2
- FIGNL1 | c.45G>A p.Q15= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs1440444059, COSV100794895; called by muse, mutect2, varscan2
- IGHV1-69D | c.352_353insGGGAGGAGAG p.*118delinsGEER | Silent (INS) | VAF 12/42 reads (29%) | called by mutect2, pindel
- KCNB2 | c.1374C>T p.F458= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as rs569733816, COSV73049167, COSV73052838; called by muse, mutect2, varscan2
- ARMC8 | c.1135-1292C>G | Intron (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- FRMD4A | c.46-149214G>C | Intron (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2
- ZSCAN32 | c.839-945C>G | Intron (SNP) | VAF 9/56 reads (16%) | catalogued as rs772317903; called by muse, mutect2, varscan2
